Gene-level copy-number profile of tumor specimen HCM-BROD-0724-C43-06A from HCMI case HCM-BROD-0724-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 74.4 years (27,189 days).
Specimen HCM-BROD-0724-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 41a54f15-6197-4b88-b849-a0561ee76d86.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0724-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,261 have no estimate.
https://portal.gdc.cancer.gov/files/037f64e1-bff7-4d56-9da9-1156d27a8b0c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 108; copy number 2: 1,725; copy number 3: 21,334; copy number 4: 18,817; copy number 5: 7,008; copy number 6: 4,093; copy number 7: 3,641; copy number 8: 312; copy number 9: 226; copy number 10: 262; copy number 11: 295; copy number 12: 123; copy number 13: 133; copy number 14: 127; copy number 15: 43; copy number 17: 56; copy number 18: 29; copy number 33: 16; copy number 44: 2; copy number 46: 9; copy number 48: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5,277 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:722,092–778,626, 4 genes, copy number 7 (within-gene range 6–7): CICP3, AL669831.1, RNU6-1199P, AL669831.2.
- chr1:143,541,768–143,760,669, 9 genes, copy number 8: AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1.
- chr3:46,712,115–46,812,574, 2 genes, copy number 7 (within-gene range 4–7): AC109583.1, PRSS50.
- chr3:46,742,092–46,812,558, 5 genes, copy number 7 (within-gene range 4–7): PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P.
- chr5:58,198–45,895,970, 679 genes, copy number 7 (broad region; genes not listed).
- chr7:63,011,463–159,233,377, 1,896 genes, copy number 7–15 (broad region; genes not listed).
- chr9:41,890,314–42,499,134, 14 genes, copy number 7: CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6.
- chr9:61,581,813–61,582,675, 1 gene, copy number 7: AL935212.3.
- chr15:48,120,990–49,620,929, 39 genes, copy number 18–48: SLC24A5, MYEF2, CTXN2, SLC12A1, AC066612.1, AC066612.2, AC023355.1, Y_RNA, DUT, FBN1, AC022467.2, AC022467.1, AC084757.3, AC084757.4, CEP152, AC084757.1, AC084757.2, AC012379.1, AC012379.2, SHC4, EID1, AC091073.1, KRT8P24, SECISBP2L, Y_RNA, RN7SL577P, AC013452.2, COPS2, Y_RNA, GALK2, NDUFAF4P1, MIR4716, AC013452.1, RN7SL307P, FAM227B, AC022306.2, AC022306.3, AC022306.1, FGF7.
- chr15:50,241,947–50,265,965, 1 gene, copy number 17 (within-gene range 3–17): HDC.
- chr15:50,275,389–50,355,408, 3 genes, copy number 17 (within-gene range 3–17): GABPB1, RNU6-94P, GABPB1-IT1.
- chr15:84,166,547–85,330,334, 52 genes, copy number 17: DNM1P41, AC136698.1, UBE2Q2L, CSPG4P11, GOLGA2P7, RN7SL331P, GOLGA6L4, UBE2Q2P8, AC243562.2, RN7SL417P, AC243562.1, DNM1P51, CSPG4P5, UBE2Q2P11, AC243562.3, Metazoa_SRP, UBE2Q2P12, AC048382.4, AC048382.3, GOLGA6L5P, AC048382.2, UBE2Q2P1, LINC00933, AC048382.5, ZSCAN2, AC048382.1, AC048382.6, SCAND2P, EGLN1P1, WDR73, Metazoa_SRP, NMB, SEC11A, AC115102.1, ZNF592, AC012291.2, ALPK3, AC012291.1, SLC28A1, AC087468.2, RNU6-339P, RNU6-796P, AC087468.1, PDE8A, AC044860.2, AC044860.1, NIFKP8, CSPG4P12, RN7SL428P, GOLGA6L3, ADAMTS7P4, AC044860.3.
- chr15:90,388,242–90,502,239, 1 gene, copy number 18 (within-gene range 4–18): IQGAP1.
- chr15:90,529,923–90,954,093, 19 genes, copy number 18 (within-gene range 4–18): CRTC3, AC103739.1, AC103739.2, CRTC3-AS1, AC103739.3, HSPE1P3, AC021422.1, LINC01585, BLM, SNORD18, AC124248.2, AC124248.1, RN7SL363P, FURIN, FES, MAN2A2, AC068831.3, HDDC3, UNC45A.
- chr18:45,034–80,247,514, 1,199 genes, copy number 7 (broad region; genes not listed).
- chr21:8,759,077–8,761,335, 1 gene, copy number 7: LINC01666.
- chr22:15,282,557–50,801,309, 1,352 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 108. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
